CGCI case BLGSP-71-30-00677 — Burkitt Lymphoma Genome Sequencing Project (CGCI-BLGSP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/fd973cd3-7bf7-47fe-bb5a-0f920bd1f804

Demographics
Sex at birth: female; Race: asian; Ethnicity: not hispanic or latino; Age at index: 73 years; Vital status: Dead; Days to death: 877 days (2.4 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Burkitt lymphoma, NOS (Includes all variants): ICD-O-3 morphology code: 9687/3; Tissue or organ of origin: Hematopoietic system, NOS; Classification of tumor: primary; Age at diagnosis: 73.9 years (26,974 days); Year of diagnosis: 2010; Method of diagnosis: Excisional Biopsy; Ann Arbor pathologic stage: Stage I; Ann Arbor B symptoms: No; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 842 days (2.3 years); Ann Arbor extranodal involvement: Yes; Burkitt lymphoma clinical variant: Sporadic, adult; Max tumor bulk site: Brain; Sites of involvement: Central nervous system.
   Pathology details: Bone marrow malignant cells: No; Tumor largest dimension diameter: 6 cm.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide + Methotrexate + Rituximab; Initial disease status: Initial Diagnosis; Days to treatment start: 29 days; Days to treatment end: 140 days; Number of cycles: 6; Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Chemotherapy; Initial disease status: Progressive Disease; Regimen or line of therapy: EPOCH-R; Days to treatment start: 161 days; Days to treatment end: 276 days; Number of cycles: 6; Treatment outcome: Partial Response.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide + Doxorubicin + Etoposide + Prednisone + Rituximab + Vincristine; Initial disease status: Progressive Disease; Days to treatment start: 161 days; Days to treatment end: 276 days; Number of cycles: 6; Treatment outcome: Partial Response.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Progressive Disease; Days to treatment start: 301 days; Days to treatment end: 336 days; Treatment dose: 45; Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Dexamethasone + Temozolomide; Initial disease status: Progressive Disease; Days to treatment start: 421 days (1.2 years); Days to treatment end: 795 days (2.2 years); Number of cycles: 6; Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis; Surgery, NOS, for recurrent disease.

Follow-up (3 entries)
- Days to follow up: 0 days; ECOG performance status: 1.
- Days to follow up: 155 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Brain, NOS; Days to recurrence: 155 days; Evidence of recurrence type: Convincing Image Source.
- Days to follow up: 842 days (2.3 years); Disease response: With Tumor.

Molecular and laboratory tests
- BCL2 (IHC): Negative.
- BCL6 (IHC): Positive; Specialized molecular test: BCL6 > 30%.
- CD10 (IHC): Positive; Specialized molecular test: CD10 > 30%.
- CD20 (IHC): Positive.
- CD3 (IHC): Negative.
- Ki67 (IHC): Positive; Specialized molecular test: Ki-67 > 90%.
- MYC translocation (FISH): Abnormal, NOS.
- MYC translocation (FISH): Positive.
- Lactate Dehydrogenase 287 [Blood test normal range upper: 240].

Other clinical attributes
- Day 0: Weight: 60 kg; Height: 156 cm; BMI: 24.7.
- Day 0: Risk factors: Rheumatoid Arthritis.
- Day 0: Immunosuppressive treatment type: Other; Risk factor treatment: Yes.
- Day 0: Comorbidities: Rheumatoid Arthritis.
- Day 0: Risk factors: Tuberculosis.
- Day 0: Comorbidities: Tuberculosis.

Biospecimens (2 samples)
- Sample BLGSP-71-30-00677-01A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Other; Preservation method: FFPE; Days to sample procurement: 0 days; Method of sample procurement: Excisional Biopsy; Tissue collection type: Retrospective.
- Sample BLGSP-71-30-00677-01Z: Sample type: Tumor; Tissue type: Tumor.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor; Lost to follow-up: No; New tumor event diagnosis indicator: Yes.
- History of disease, History immunological diseases: History immunological disease: Rheumatoid Arthritis.
- History of disease: History immunosuppressive prescription other: biologic agent; History immunosuppresive diagnosis other: Tuberculosis.
- Primary pathology: Histologic diagnosis: Burkitt lymphoma (BL), classic morphology; Extranodal site involvement: 1; Extranodal involvment other: CNS - temporo-occipital region; Lymph nodes examined: No.
- Primary pathology, Lymph node involvement sites: Lymph node involvement site: No Known Nodal Involvement.
- Stage record, Ann arbor: B symptoms present indicator: No.
- Tests performed: LDH level: 287; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 2: Immunophenotypic analysis tested: CD20.
- Tests performed, Genetic testing results, Genetic testing result 5: Immunophenotypic analysis tested: BCL2.
- Tests performed, Genetic testing results, Genetic testing result 6: Immunophenotypic analysis tested: CD3.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result 1: Genetic abnormality tested: C-myc.
- New tumor event: New tumor event type: Locoregional Recurrence; New tumor event diagnosis evidence: Convincing Imaging; New tumor event surgery: No; New tumor event radiation treatment: Yes; New tumor event pharmaceutical treatment: Yes.
- Treatments, Treatment 1: Therapy regimen: Initial; Chemo end reporting period: Yes; Pharmaceutical regimen: Other Pharmaceutical Regimen (please specify); Pharmaceutical regimen other: Cyclophosphamide, Rituximab, Methotrexate; Pharma adjuvant cycles count: 6; Treatment best response: Clinical Progressive Disease.
- Treatments, Treatment 2: Therapy regimen: Progression after initial; Chemo end reporting period: Yes; Pharmaceutical regimen: Other Pharmaceutical Regimen (please specify); Pharma adjuvant cycles count: 6.
- Treatments, Treatment 3: Therapy regimen: Progression after initial; Treatment type: Radiation Therapy; Radiation therapy end: Yes; Radiation therapy total dosage: 45; Treatment best response: Clinical Progressive Disease.
- Treatments, Treatment 4: Therapy regimen: Progression after initial; Chemo end reporting period: Yes; Pharmaceutical regimen: Other Pharmaceutical Regimen (please specify); Pharmaceutical regimen other: Dexamethasone, Temozolomide; Pharma adjuvant cycles count: 6; Treatment best response: Clinical Progressive Disease.

Additional fields from the CGCI biospecimen supplement workbook CGCI-BLGSP_biospecimenSupplementSpreadsheet_TWIST_20220304.xlsx (sheet Sheet1), for sample BLGSP-71-30-00677-01A-01E-0001-01:
- % tumour: 95
